Somatic mutation profile of tumor specimen TCGA-60-2719-01A (aliquot TCGA-60-2719-01A-01W-0877-08) from TCGA case TCGA-60-2719, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 83.2 years (30,379 days).
Specimen TCGA-60-2719-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0ad9bd1-e191-4fa9-bbac-dc4e7f95b575.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2719-11A (Solid Tissue Normal), aliquot TCGA-60-2719-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc9a661e-ee00-426e-b3a4-60516a1cc48d

The open-access MAF lists 205 somatic variants for this specimen: 151 protein-altering or splice-affecting, 50 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 137, Silent 50, Frame Shift Del 6, Nonsense Mutation 4, Splice Site 3, Intron 3, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRHPR | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as rs774654020, COSV58942491; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- TP53 | c.577C>G p.H193D | Missense Mutation (SNP) | VAF 77/112 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876658468, COSV52675896, COSV52688299, COSV52757395; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB6 | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1347611536, COSV54695194; called by muse, mutect2, varscan2
- ACTC1 | c.278A>G p.Y93C | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV51758685; called by muse, mutect2, varscan2
- AFF3 | c.3037G>A p.E1013K | Missense Mutation (SNP) | VAF 129/339 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768278281, COSV57851457; called by muse, mutect2, varscan2
- ARHGAP29 | c.335T>C p.V112A | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53110783; called by muse, mutect2, varscan2
- ARHGAP32 | c.3104C>T p.P1035L (on ENST00000310343 / NM_001378025.1; = p.P686L on NM_014715.4) | Missense Mutation (SNP) | VAF 291/642 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs1276229536, COSV59842740, COSV59846395; called by muse, mutect2, varscan2
- ARHGAP36 | c.649C>A p.Q217K | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV52265928; called by muse, mutect2, varscan2
- BAZ2B | c.673A>G p.R225G | Missense Mutation (SNP) | VAF 225/615 reads (37%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.966); catalogued as COSV58599250; called by muse, mutect2, varscan2
- BTN1A1 | c.539C>A p.S180Y | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV55067348; called by muse, mutect2, varscan2
- C3 | c.2244G>T p.R748S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV55571807; called by muse, mutect2, varscan2
- CACNA1A | c.5448G>T p.M1816I | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV64214605; called by muse, mutect2
- CACNA1F | c.2876C>T p.S959F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59904066; called by muse, mutect2, varscan2
- CCDC85A | c.1123G>A p.G375R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.031); catalogued as rs372992628, COSV101339564; called by muse, mutect2, varscan2
- CDK2AP1 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as COSV55542407; called by muse, mutect2, varscan2
- CENPI | c.1900A>T p.S634C | Missense Mutation (SNP) | VAF 82/205 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV54501905; called by muse, mutect2, varscan2
- CEP85L | c.1826A>G p.N609S | Missense Mutation (SNP) | VAF 174/430 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV63822385; called by muse, mutect2, varscan2
- CEP89 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 81/246 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs758497289, COSV59863689; called by muse, mutect2, varscan2
- CERK | c.1228G>C p.A410P | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as COSV53450940; called by muse, mutect2, varscan2
- CFAP61 | c.1916C>T p.A639V | Missense Mutation (SNP) | VAF 132/335 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.226); catalogued as rs759937819, COSV55626654; called by muse, mutect2, varscan2
- CFAP61 | c.2837C>T p.T946M | Missense Mutation (SNP) | VAF 475/1277 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs140045830; called by muse, varscan2
- CLCN4 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as COSV66466209; called by muse, mutect2
- CNOT1 | c.1781A>G p.Y594C | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100409329; called by muse, mutect2
- CNOT4 | c.1675G>T p.G559W (on ENST00000541284 / NM_001190850.1; = p.G556W on NM_001190849.2) | Missense Mutation (SNP) | VAF 225/684 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64157447; called by muse, mutect2, varscan2
- COL11A1 | c.1640G>T p.G547V | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62180749; called by muse, mutect2, varscan2
- COL11A2 | c.3752C>T p.P1251L (on ENST00000341947 / NM_080680.3; = p.P1144L on NM_080679.2) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV59494559; called by muse, varscan2
- CPXM1 | c.2189G>T p.R730M | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV66044961, COSV66045145; called by muse, mutect2, varscan2
- CR2 | c.1841C>T p.S614F | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as COSV65507274; called by muse, mutect2, varscan2
- CRYM | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 133/221 reads (60%) | SIFT tolerated (0.76); PolyPhen benign (0.07); catalogued as COSV54830685, COSV54832735; called by muse, mutect2, varscan2
- CSMD1 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.673); catalogued as COSV68195198; called by muse, mutect2, varscan2
- CST8 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 109/207 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV55670938, COSV55671798; called by muse, mutect2, varscan2
- CTNNA2 | c.514C>A p.L172I | Missense Mutation (SNP) | VAF 94/272 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV63560838; called by muse, mutect2, varscan2
- CTSG | c.410G>A p.R137K | Missense Mutation (SNP) | VAF 189/474 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV53535022; called by muse, mutect2, varscan2
- CYBB | c.1122G>T p.Q374H | Missense Mutation (SNP) | VAF 241/549 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.421); catalogued as COSV66085227; called by muse, mutect2, varscan2
- CYFIP2 | c.2971T>A p.Y991N (on ENST00000616178 / NM_001291722.2; = p.Y966N on NM_014376.4) | Missense Mutation (SNP) | VAF 145/224 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV59035006; called by muse, mutect2, varscan2
- CYP11B1 | c.1222T>C p.Y408H | Missense Mutation (SNP) | VAF 193/359 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52826367; called by muse, mutect2, varscan2
- DLL4 | c.1298C>T p.T433M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs760234335; called by muse, mutect2, varscan2
- DNAH11 | c.1700C>G p.A567G | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.253); catalogued as rs545970834; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH11 | c.3802T>A p.Y1268N | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV60952427; called by muse, mutect2, varscan2
- DNAH11 | c.7125C>A p.S2375R | Missense Mutation (SNP) | VAF 148/443 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV60952445; called by muse, mutect2, varscan2
- DNAH8 | c.5546G>A p.G1849D | Missense Mutation (SNP) | VAF 197/462 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59440079; called by muse, mutect2, varscan2
- DSC1 | c.1249T>C p.C417R | Missense Mutation (SNP) | VAF 84/294 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs372473569; called by muse, mutect2, varscan2
- ELMO1 | c.395T>C p.M132T | Missense Mutation (SNP) | VAF 69/230 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV60302153; called by muse, mutect2, varscan2
- ENOX2 | c.100A>G p.M34V (on ENST00000338144 / NM_001382520.1; = p.M5V on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/302 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV57650400; called by muse, mutect2, varscan2
- EPHA5 | c.3020G>T p.R1007L | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV56640997; called by muse, mutect2, varscan2
- EPHB3 | c.1854T>A p.N618K | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV57805445; called by muse, mutect2
- FAM120C | c.1387G>C p.G463R | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as COSV60258899; called by muse, mutect2, varscan2
- FAM135B | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 190/820 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV52719571; called by muse, mutect2, varscan2
- FANCA | c.3640G>C p.E1214Q | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.37); PolyPhen benign (0.046); catalogued as COSV57067556; called by muse, mutect2, varscan2
- FAT4 | c.2937T>A p.S979R | Missense Mutation (SNP) | VAF 69/128 reads (54%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.995); catalogued as COSV67884580; called by muse, mutect2
- FBXO11 | c.2590A>G p.I864V (on ENST00000403359 / NM_001190274.2; = p.I780V on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 307/891 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373629400, COSV99315264; called by muse, mutect2, varscan2
- FBXO47 | c.44A>G p.Q15R | Missense Mutation (SNP) | VAF 145/218 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV65241633; called by muse, mutect2, varscan2
- FIG4 | c.623G>T p.G208V | Missense Mutation (SNP) | VAF 156/450 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.376); catalogued as COSV100020380, COSV57786991; called by muse, mutect2, varscan2
- FILIP1L | c.247C>A p.L83M | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV58768069; called by muse, mutect2, varscan2
- FLNA | c.7894T>A p.W2632R (on ENST00000369850 / NM_001110556.2; = p.W2624R on NM_001456.3) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61041632; called by muse, mutect2, varscan2
- GABRG2 | c.1267C>G p.R423G (on ENST00000361925 / NM_001375343.1; = p.R383G on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/118 reads (52%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.995); catalogued as COSV62716095, COSV62717375, COSV62718640; called by muse, mutect2, varscan2
- GMFG | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 65/333 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.334); catalogued as COSV53419156; called by muse, mutect2, varscan2
- GPR143 | c.358G>C p.A120P | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV66632294; called by muse, mutect2, varscan2
- GRID2 | c.2124G>C p.M708I | Missense Mutation (SNP) | VAF 79/150 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV56196288; called by muse, mutect2, varscan2
- GRM1 | c.2362G>C p.A788P | Missense Mutation (SNP) | VAF 178/445 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51110462, COSV51132186; called by muse, mutect2, varscan2
- GRM3 | c.1163C>A p.S388Y | Missense Mutation (SNP) | VAF 58/383 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64470566; called by muse, mutect2, varscan2
- GSR | c.416A>G p.N139S | Missense Mutation (SNP) | VAF 56/77 reads (73%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV55320342; called by muse, mutect2, varscan2
- HECW1 | c.2612G>C p.R871T | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV67827364; called by muse, mutect2, varscan2
- HSD17B7 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV54418080; called by muse, mutect2, varscan2
- IGDCC4 | c.2727G>T p.E909D | Missense Mutation (SNP) | VAF 77/181 reads (43%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as COSV61536371; called by muse, mutect2, varscan2
- ITGAV | c.746A>G p.D249G | Missense Mutation (SNP) | VAF 50/373 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV53711655; called by muse, mutect2, varscan2
- KCNH8 | c.1177+1G>A p.X393_splice | Splice Site (SNP) | VAF 40/70 reads (57%) | catalogued as COSV60461737; called by muse, mutect2, varscan2
- KCNS2 | c.179A>G p.D60G | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54638198; called by muse, mutect2, varscan2
- KCTD9 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55339890; called by muse, mutect2, varscan2
- KDM1A | c.1450C>G p.H484D | Missense Mutation (SNP) | VAF 171/544 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.23); catalogued as COSV63087569; called by muse, mutect2, varscan2
- KISS1 | c.345C>A p.N115K | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM121480; called by muse, mutect2, varscan2
- KRT6C | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 72/243 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as rs1314732181, COSV99359965; called by muse, mutect2, varscan2
- LIN9 | c.541C>T p.R181C (on ENST00000366808 / NM_001270410.2; = p.R126C on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100068020, COSV60243919; called by muse, mutect2, varscan2
- LONRF3 | c.1402G>A p.A468T (on ENST00000371628 / NM_001031855.3; = p.A427T on NM_024778.5) | Missense Mutation (SNP) | VAF 265/521 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as rs747526914, COSV100504244, COSV59151681; called by muse, mutect2, varscan2
- LRRC7 | c.127C>T p.R43W (on ENST00000651989 / NM_001370785.2; = p.R10W on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150507629; called by muse, mutect2, varscan2
- MAP3K19 | c.35A>G p.E12G | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as COSV59638154; called by muse, mutect2, varscan2
- MPP1 | c.1026C>A p.N342K | Missense Mutation (SNP) | VAF 236/564 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV65729398; called by muse, varscan2
- MTMR1 | c.351C>A p.C117* | Nonsense Mutation (SNP) | VAF 99/290 reads (34%) | catalogued as COSV64897545; called by muse, mutect2, varscan2
- MUC16 | c.1813G>T p.V605F | Missense Mutation (SNP) | VAF 103/296 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.271); catalogued as rs540756541, COSV67461210; called by muse, mutect2, varscan2
- MYF6 | c.164A>T p.D55V | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.773); catalogued as COSV57351361, COSV99952666; called by muse, mutect2, varscan2
- MYH2 | c.3745-1G>C p.X1249_splice | Splice Site (SNP) | VAF 53/90 reads (59%) | catalogued as COSV55436260; called by muse, mutect2, varscan2
- MYH7 | c.2060C>A p.P687H | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.841); catalogued as rs747382784, COSV62518462; called by muse, mutect2, varscan2
- NAP1L3 | c.848G>T p.R283I | Missense Mutation (SNP) | VAF 144/322 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV59074893; called by muse, mutect2, varscan2
- NAV1 | c.2663T>A p.L888H | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55216713; called by muse, mutect2, varscan2
- NCAM2 | c.1642C>A p.H548N | Missense Mutation (SNP) | VAF 61/93 reads (66%) | SIFT tolerated (0.27); PolyPhen benign (0.319); catalogued as COSV53069880; called by muse, mutect2, varscan2
- NUP153 | c.346A>G p.T116A | Missense Mutation (SNP) | VAF 81/208 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs757499762, COSV50448480; called by muse, mutect2, varscan2
- OBSCN | c.12514G>A p.A4172T | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.572); catalogued as COSV52765560; called by muse, mutect2, varscan2
- OR10C1 | c.283C>T p.R95C (on ENST00000622521; = p.R93C on NM_013941.3) | Missense Mutation (SNP) | VAF 207/597 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs758622473, COSV101010806, COSV65822587; called by muse, mutect2, varscan2
- OR12D3 | c.692G>T p.R231I | Missense Mutation (SNP) | VAF 123/305 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV65827529; called by muse, mutect2, varscan2
- OR2T10 | c.195G>C p.Q65H | Missense Mutation (SNP) | VAF 114/289 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.873); catalogued as COSV57896673; called by muse, mutect2, varscan2
- OR4Q3 | c.732G>T p.K244N | Missense Mutation (SNP) | VAF 143/1028 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV59178333; called by muse, mutect2, varscan2
- OR56A4 | c.1005C>A p.H335Q | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58109953; called by muse, mutect2, varscan2
- OR6A2 | c.928C>G p.L310V | Missense Mutation (SNP) | VAF 157/356 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV60264822, COSV60265914; called by muse, mutect2, varscan2
- OR8H1 | c.200C>A p.S67* | Nonsense Mutation (SNP) | VAF 189/610 reads (31%) | catalogued as rs371274663, COSV57293780, COSV57295689; called by muse, mutect2, varscan2
- OSBP2 | c.2354T>C p.L785P | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60241863; called by muse, mutect2, varscan2
- PATJ | c.3875A>G p.N1292S | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.257); catalogued as rs1027119284, COSV56249068; called by muse, mutect2, varscan2
- PCOLCE | c.894dup p.K299Qfs*16 | Frame Shift Ins (INS) | VAF 5/39 reads (13%) | catalogued as rs755349242; called by mutect2, pindel, varscan2
- PDK1 | c.403A>G p.I135V | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV56375063; called by muse, mutect2, varscan2
- PDK3 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV64793299; called by muse, mutect2, varscan2
- PEX16 | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as COSV53801721; called by muse, mutect2
- PHEX | c.2057T>C p.L686P | Missense Mutation (SNP) | VAF 220/553 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV65075049; called by muse, mutect2, varscan2
- PKM | c.1127G>T p.R376L | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs760211346, COSV58788035; called by muse, mutect2, varscan2
- PLEKHG1 | c.3983G>A p.R1328H | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs754481715, COSV62045900; called by muse, mutect2
- PPHLN1 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 106/294 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as rs1002324575, COSV56730300; called by muse, mutect2, varscan2
- PPP1R12C | c.2285A>T p.D762V | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52381498; called by muse, mutect2, varscan2
- PWWP3B | c.476A>T p.E159V | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.93); catalogued as COSV61799324; called by muse, mutect2, varscan2
- RSBN1 | c.554A>G p.H185R | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.702); catalogued as rs747313984, COSV54732126; called by muse, mutect2, varscan2
- RTTN | c.4570G>T p.D1524Y | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55343774; called by muse, mutect2, varscan2
- SEMA6C | c.770G>T p.R257L | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59002177; called by muse, mutect2, varscan2
- SEMA6D | c.2434A>G p.S812G (on ENST00000316364 / NM_153618.2; = p.S750G on NM_020858.2) | Missense Mutation (SNP) | VAF 67/243 reads (28%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.837); catalogued as rs1483806899, COSV60375943; called by muse, mutect2, varscan2
- SEPTIN6 | c.1213C>A p.L405M | Missense Mutation (SNP) | VAF 102/214 reads (48%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); catalogued as COSV59713530, COSV59717603; called by muse, mutect2, varscan2
- SERPINA1 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 81/144 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63345557, COSV63345682; called by muse, mutect2, varscan2
- SF3B1 | c.554A>G p.N185S | Missense Mutation (SNP) | VAF 222/540 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV59212351; called by muse, varscan2
- SH3YL1 | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 72/186 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV62156133; called by muse, varscan2
- SLC6A18 | c.634A>C p.T212P | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777600288; called by muse, mutect2
- SPATA5L1 | c.1242G>T p.E414D | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.144); catalogued as COSV59744449; called by muse, mutect2, varscan2
- SPATS2L | c.203A>G p.N68S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); catalogued as COSV62347513; called by muse, mutect2, varscan2
- SPDYA | c.347G>T p.S116I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.329); catalogued as COSV61855865; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2900T>A p.V967E | Missense Mutation (SNP) | VAF 83/221 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV59129341; called by muse, mutect2, varscan2
- SYTL5 | c.1486T>A p.W496R | Missense Mutation (SNP) | VAF 361/758 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52900262; called by muse, mutect2, varscan2
- TAPBP | c.1147C>T p.R383* | Nonsense Mutation (SNP) | VAF 19/138 reads (14%) | catalogued as rs79026906, COSV70457050; called by muse, mutect2, varscan2
- TBC1D25 | c.773T>A p.M258K | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV65123558; called by muse, mutect2, varscan2
- TEPP | c.269C>A p.A90E | Missense Mutation (SNP) | VAF 56/83 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV52043092, COSV52043171; called by muse, mutect2, varscan2
- TIMD4 | c.13C>A p.P5T | Missense Mutation (SNP) | VAF 89/170 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV50854853; called by muse, mutect2, varscan2
- TMEM119 | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767276293, COSV67188632; called by muse, mutect2, varscan2
- TNXB | c.9940A>T p.T3314S (on ENST00000647633; = p.T3067S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.26); catalogued as COSV64477791; called by muse, mutect2, varscan2
- TRAM1 | c.493A>G p.M165V | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1360120862, COSV51597841; called by muse, mutect2, varscan2
- TXLNB | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 77/228 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs147752054; called by muse, mutect2, varscan2
- UBE3D | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 93/236 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52753047; called by muse, mutect2, varscan2
- UBR4 | c.7125G>T p.M2375I | Missense Mutation (SNP) | VAF 67/278 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.38); catalogued as COSV64387606; called by muse, varscan2
- UBR4 | c.7124T>A p.M2375K | Missense Mutation (SNP) | VAF 66/279 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.599); catalogued as COSV64387624; called by muse, varscan2
- USP28 | c.2473C>T p.L825F | Missense Mutation (SNP) | VAF 108/202 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50159627; called by muse, mutect2, varscan2
- WT1 | c.1024T>G p.Y342D | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV60070383, COSV60076178, COSV99070050; called by muse, mutect2, varscan2
- XKR3 | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 118/350 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV58885777; called by muse, mutect2, varscan2
- ZBBX | c.2209A>G p.S737G | Missense Mutation (SNP) | VAF 242/356 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV56787522; called by muse, mutect2, varscan2
- ZC3H12B | c.1358T>C p.I453T | Missense Mutation (SNP) | VAF 66/131 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV59047483; called by muse, mutect2, varscan2
- ZC3H14 | c.224C>G p.S75C | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as rs1416882045, COSV51768639; called by muse, varscan2
- ZDHHC17 | c.819G>T p.M273I | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.063); catalogued as COSV58351272; called by muse, mutect2, varscan2
- ZNF700 | c.1597G>C p.E533Q | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.331); catalogued as COSV54312030; called by muse, mutect2, varscan2
- ZNF75D | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 195/407 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0.014); catalogued as COSV66132551, COSV66132641; called by muse, mutect2, varscan2
- ASTN1 | c.823del p.L275Cfs*23 | Frame Shift Del (DEL) | VAF 102/252 reads (40%) | called by mutect2, varscan2
- CUL9 | c.7069_7070delinsG p.Q2357Gfs*83 | Frame Shift Del (DEL) | VAF 45/240 reads (19%) | called by pindel, varscan2*
- FBN1 | c.6859_6871+8del p.X2287_splice | Splice Site (DEL) | VAF 49/311 reads (16%) | called by mutect2, pindel*
- IGKV1D-17 | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 127/383 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- LCAT | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.021); called by muse, mutect2
- MR1 | c.115del p.H39Mfs*50 | Frame Shift Del (DEL) | VAF 26/64 reads (41%) | called by mutect2, varscan2
- MRPS15 | c.232A>G p.N78D | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- NEURL4 | c.377del p.G126Afs*4 | Frame Shift Del (DEL) | VAF 12/22 reads (55%) | called by mutect2, pindel, varscan2
- OR4D6 | c.840del p.M281Cfs*2 | Frame Shift Del (DEL) | VAF 204/609 reads (33%) | called by mutect2, pindel, varscan2
- PCLO | c.8078G>T p.S2693I | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.155); called by muse, mutect2
- USF3 | c.2151_2158del p.S717Rfs*13 | Frame Shift Del (DEL) | VAF 25/127 reads (20%) | called by mutect2, varscan2
- AMELX | c.267A>G p.P89= | Silent (SNP) | VAF 103/518 reads (20%) | catalogued as COSV61626651; called by muse, mutect2, varscan2
- AMPD3 | c.567A>G p.A189= (on ENST00000396553 / NM_001025389.2; = p.A198= on NM_000480.3) | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV67330671; called by muse, mutect2, varscan2
- ARSL | c.681C>T p.V227= | Silent (SNP) | VAF 14/273 reads (5%) | called by muse, mutect2
- ATXN7 | c.2136A>G p.P712= | Silent (SNP) | VAF 34/56 reads (61%) | catalogued as rs375913531; called by muse, mutect2, varscan2
- CDK14 | c.495G>A p.V165= (on ENST00000380050 / NM_001287135.2; = p.V147= on NM_012395.3) | Silent (SNP) | VAF 122/331 reads (37%) | catalogued as COSV56032273; called by muse, mutect2, varscan2
- CLYBL | c.747A>T p.R249= | Silent (SNP) | VAF 61/109 reads (56%) | catalogued as COSV59220424; called by muse, mutect2, varscan2
- CREBBP | c.2103G>A p.V701= | Silent (SNP) | VAF 110/193 reads (57%) | catalogued as COSV52120751; called by muse, mutect2, varscan2
- CTNND2 | c.1500G>T p.A500= | Silent (SNP) | VAF 159/254 reads (63%) | catalogued as COSV58882457; called by muse, mutect2, varscan2
- DNAAF4 | c.177T>C p.D59= | Silent (SNP) | VAF 117/334 reads (35%) | catalogued as COSV58248287; called by muse, mutect2, varscan2
- DNAH11 | c.6000T>A p.A2000= | Silent (SNP) | VAF 234/629 reads (37%) | catalogued as COSV60952435; called by muse, mutect2, varscan2
- FABP5 | c.129T>C p.C43= | Silent (SNP) | VAF 88/169 reads (52%) | catalogued as rs143988575, COSV51917335; called by muse, mutect2, varscan2
- FLNC | c.6015C>T p.F2005= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs771715893, COSV57954517; ClinVar: likely benign; called by muse, mutect2, varscan2
- FZD1 | c.1158C>T p.A386= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as rs933505230, COSV55310050; called by muse, mutect2, varscan2
- GABRQ | c.1833C>A p.S611= | Silent (SNP) | VAF 65/163 reads (40%) | catalogued as COSV64781696; called by muse, mutect2, varscan2
- GHSR | c.75C>T p.P25= | Silent (SNP) | VAF 23/112 reads (21%) | catalogued as COSV53838586, COSV99576870; called by muse, mutect2, varscan2
- GRIK1 | c.810T>C p.Y270= | Silent (SNP) | VAF 66/101 reads (65%) | catalogued as rs748344722, COSV58716151; called by muse, mutect2, varscan2
- IGF2R | c.7269G>T p.S2423= | Silent (SNP) | VAF 86/230 reads (37%) | catalogued as COSV63626540, COSV63628395; called by muse, mutect2, varscan2
- IGKV1-9 | c.342T>C p.N114= | Silent (SNP) | VAF 122/276 reads (44%) | called by muse, mutect2, varscan2
- INO80D | c.870C>T p.F290= | Silent (SNP) | VAF 43/147 reads (29%) | catalogued as COSV68958695; called by muse, mutect2, varscan2
- INSC | c.1200G>A p.T400= | Silent (SNP) | VAF 52/129 reads (40%) | catalogued as rs749848116, COSV65410072; called by muse, mutect2, varscan2
- ITGA11 | c.3129C>T p.Y1043= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV59875727; called by muse, mutect2, varscan2
- KIAA1210 | c.2586T>G p.T862= | Silent (SNP) | VAF 71/148 reads (48%) | catalogued as COSV68176324, COSV68176710; called by muse, mutect2, varscan2
- KIDINS220 | c.978T>G p.P326= | Silent (SNP) | VAF 112/327 reads (34%) | catalogued as COSV56752514; called by muse, mutect2, varscan2
- KLRC1 | c.453C>T p.N151= | Silent (SNP) | VAF 228/632 reads (36%) | catalogued as COSV61725105; called by muse, varscan2
- LRIG1 | c.1683C>A p.I561= | Silent (SNP) | VAF 135/217 reads (62%) | catalogued as COSV56239166; called by muse, mutect2, varscan2
- LRRTM1 | c.1359C>T p.F453= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as COSV54440346; called by muse, mutect2, varscan2
- MAMLD1 | c.993G>T p.L331= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV53374099; called by muse, mutect2, varscan2
- MAPRE2 | c.327G>A p.K109= | Silent (SNP) | VAF 45/124 reads (36%) | catalogued as COSV55818630; called by muse, mutect2, varscan2
- MLLT10 | c.822T>A p.S274= | Silent (SNP) | VAF 51/80 reads (64%) | catalogued as COSV56994535; called by muse, mutect2, varscan2
- NEIL3 | c.966C>T p.T322= | Silent (SNP) | VAF 222/387 reads (57%) | catalogued as COSV52809938; called by muse, mutect2, varscan2
- NLRP3 | c.1392C>A p.L464= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV60223034; called by muse, mutect2, varscan2
- OR51A4 | c.663G>C p.L221= | Silent (SNP) | VAF 46/163 reads (28%) | catalogued as COSV66749341; called by muse, mutect2, varscan2
- OR8D2 | c.108G>C p.V36= | Silent (SNP) | VAF 251/724 reads (35%) | catalogued as COSV62488385; called by muse, mutect2, varscan2
- POM121 | c.1677G>A p.S559= (on ENST00000434423; = p.S294= on NM_172020.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs374180328; called by mutect2, varscan2
- PORCN | c.795G>T p.T265= (on ENST00000326194 / NM_203475.3; = p.T254= on NM_022825.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as COSV58226048; called by muse, mutect2, varscan2
- SH3PXD2B | c.1569T>A p.P523= | Silent (SNP) | VAF 53/70 reads (76%) | catalogued as COSV61126297; called by muse, mutect2, varscan2
- SLC18A2 | c.552C>T p.F184= | Silent (SNP) | VAF 167/291 reads (57%) | catalogued as rs1354793907, COSV53690074; called by muse, mutect2, varscan2
- SLC27A4 | c.594C>T p.L198= | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as rs910754754, COSV55959664; called by muse, mutect2, varscan2
- SLCO1A2 | c.96C>G p.S32= | Silent (SNP) | VAF 11/249 reads (4%) | catalogued as COSV56604578; called by muse, mutect2
- SRSF11 | c.1317A>G p.K439= | Silent (SNP) | VAF 39/87 reads (45%) | catalogued as COSV63936936; called by muse, mutect2, varscan2
- ST8SIA1 | c.16C>A p.R6= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV53953281; called by muse, mutect2, varscan2
- STAG1 | c.2949G>A p.E983= | Silent (SNP) | VAF 43/120 reads (36%) | catalogued as COSV52607348; called by muse, mutect2, varscan2
- STAR | c.537G>A p.V179= | Silent (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- SWT1 | c.1326C>G p.A442= | Silent (SNP) | VAF 107/344 reads (31%) | catalogued as COSV62254561; called by mutect2, varscan2
- TCTE1 | c.1227C>G p.L409= | Silent (SNP) | VAF 43/153 reads (28%) | catalogued as COSV65255427; called by muse, mutect2, varscan2
- TIMP4 | c.420G>T p.L140= | Silent (SNP) | VAF 204/309 reads (66%) | catalogued as COSV55139005; called by muse, mutect2, varscan2
- TMEM51 | c.282C>T p.G94= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs1185801385, COSV65690876; called by muse, mutect2, varscan2
- TTN | c.22647T>C p.Y7549= (on ENST00000591111; = p.Y6622= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV60000743; called by muse, mutect2, varscan2
- UNC79 | c.4965C>T p.G1655= (on ENST00000393151 / NM_001346218.2; = p.G1478= on NM_020818.5) | Silent (SNP) | VAF 48/249 reads (19%) | catalogued as COSV56383788; called by muse, mutect2, varscan2
- VSIG1 | c.579C>A p.T193= | Silent (SNP) | VAF 274/903 reads (30%) | catalogued as COSV54258834; called by muse, mutect2, varscan2
- C16orf91 | c.*70C>T | 3'UTR (SNP) | VAF 18/32 reads (56%) | catalogued as rs1249930491; called by muse, mutect2, varscan2
- KPNA4 | c.1032+526G>T | Intron (SNP) | VAF 108/523 reads (21%) | catalogued as rs1226061850, COSV100515072; called by muse, mutect2, varscan2
- RBPMS2 | c.88-10868A>G | Intron (SNP) | VAF 27/64 reads (42%) | catalogued as COSV55604199; called by muse, mutect2, varscan2
- TPTE2 | c.1395+685G>C | Intron (SNP) | VAF 34/93 reads (37%) | catalogued as rs756946543; called by muse, mutect2, varscan2
